Somatic mutation profile of tumor specimen TCGA-06-0875-01A (aliquot TCGA-06-0875-01A-01D-1492-08) from TCGA case TCGA-06-0875, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.1 years (22,312 days).
Specimen TCGA-06-0875-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3524e49-fcab-492c-a2d5-f7d9d504e25d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0875-10A (Blood Derived Normal), aliquot TCGA-06-0875-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcf0f482-a35f-45da-be4b-e3773c11c106

The open-access MAF lists 68 somatic variants for this specimen: 54 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 47, Silent 14, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.3507+1G>A p.X1169_splice (on ENST00000265723 / NM_018849.3; = p.X1162_splice on NM_000443.4) | Splice Site (SNP) | VAF 53/417 reads (13%) | catalogued as rs764513998, COSV55941506; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs587782350, CM991083, COSV64291511, COSV64305247; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 40/64 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.7645C>T p.R2549C (on ENST00000560601 / NM_001369268.1; = p.R2412C on NM_001135.3) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs571382991, COSV61358532; called by muse, mutect2
- ADAM32 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs762485084, COSV65949924; called by muse, mutect2, varscan2
- AGPAT2 | c.758G>T p.R253M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.269); catalogued as COSV58248725; called by muse, mutect2
- AGRN | c.2873G>A p.G958D | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.456); catalogued as COSV65069928; called by muse, mutect2, varscan2
- AKAP13 | c.7075C>G p.R2359G (on ENST00000394518 / NM_007200.5; = p.R2363G on NM_006738.6) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs778806648, COSV63460084; called by muse, mutect2, varscan2
- AMPH | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 127/549 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167299845, COSV57743752; called by muse, mutect2, varscan2
- ASB11 | c.624G>T p.R208S | Missense Mutation (SNP) | VAF 87/420 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV60355403; called by muse, mutect2, varscan2
- ATP10D | c.3362A>T p.N1121I | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56713014; called by muse, mutect2
- BSN | c.10022C>T p.P3341L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV56527039; called by muse, mutect2, varscan2
- C12orf4 | c.284T>G p.L95* | Nonsense Mutation (SNP) | VAF 70/156 reads (45%) | catalogued as COSV54207423; called by muse, mutect2, varscan2
- CCN6 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as COSV57889467; called by muse, varscan2
- CDKL1 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53579882; called by muse, mutect2, varscan2
- CELSR3 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 98/234 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs144228630; called by muse, mutect2, varscan2
- CIDEA | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs149949331; called by muse, mutect2, varscan2
- CLDN18 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 104/272 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs772493450, COSV59302428, COSV59302939; called by muse, mutect2, varscan2
- CYP3A43 | c.659T>C p.L220S | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV55936427; called by muse, mutect2, varscan2
- FLG | c.4649C>G p.S1550* | Nonsense Mutation (SNP) | VAF 261/682 reads (38%) | catalogued as COSV64242625; called by muse, mutect2, varscan2
- GPR141 | c.74T>A p.F25Y | Missense Mutation (SNP) | VAF 58/542 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as COSV57733996; called by muse, mutect2, varscan2
- GPS1 | c.1433T>C p.L478P | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.101); catalogued as rs781260119, COSV57649357; called by muse, mutect2, varscan2
- GRPR | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 70/301 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs867462308, COSV66669550; called by muse, mutect2, varscan2
- IDO1 | c.1018G>C p.V340L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.564); catalogued as COSV53716307; called by muse, mutect2, varscan2
- IL12B | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs771683283, COSV51455193; called by muse, mutect2, varscan2
- KANK1 | c.2717C>G p.T906S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV63212618; called by muse, mutect2, varscan2
- KARS1 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs761886340, COSV56694369; called by mutect2, varscan2
- KDM1B | c.1697C>T p.A566V (on ENST00000449850; = p.A334V on NM_153042.4) | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV52811335; called by muse, mutect2, varscan2
- LRRC55 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs201169874; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1625A>G p.Y542C | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs1409806572, COSV53797057; called by muse, mutect2, varscan2
- MDGA2 | c.2415T>C p.S805= (on ENST00000399232 / NM_001113498.2; = p.S507= on NM_182830.4) | Splice Region (SNP) | VAF 4/15 reads (27%) | catalogued as COSV62114705; called by muse, mutect2, varscan2
- MRGPRE | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768186461, COSV67745982; called by muse, mutect2, varscan2
- MRGPRX2 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as rs753275049, COSV61674269; called by muse, mutect2, varscan2
- MUC16 | c.35227G>A p.V11743M | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.192); catalogued as rs551319234, COSV67480130; called by muse, mutect2, varscan2
- NIPA1 | c.987C>A p.D329E | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV61680009; called by muse, mutect2, varscan2
- NIPAL2 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs145862248; called by muse, mutect2, varscan2
- NME8 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs144650767; called by muse, mutect2, varscan2
- NUCB1 | c.439C>G p.H147D | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.255); catalogued as COSV54388192; called by muse, mutect2, varscan2
- PAGE2B | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV66611364; called by muse, mutect2, varscan2
- PPP1CC | c.410A>T p.Y137F | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.321); catalogued as COSV58585112; called by muse, mutect2, varscan2
- PRSS35 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 68/143 reads (48%) | catalogued as rs773975931, COSV63800668; called by muse, mutect2, varscan2
- PTEN | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as COSV64289872, COSV64299283; called by muse, mutect2, varscan2
- RNF169 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372547886, COSV55132919; called by muse, mutect2, varscan2
- RUSC2 | c.3747G>T p.E1249D | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.037); catalogued as COSV63428830; called by muse, mutect2, varscan2
- SAMD9L | c.1334A>G p.E445G | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV59085115; called by muse, mutect2, varscan2
- SLC16A6 | c.1247A>C p.E416A | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as rs1555748272, COSV59177632; called by muse, mutect2, varscan2
- TAT | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs774749746, COSV63532262, COSV63533172; called by muse, mutect2, varscan2
- TGFBR2 | c.1585C>T p.L529F | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM064335, COSV55450870; called by muse, mutect2, varscan2
- TM2D1 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.133); catalogued as rs757751061, COSV53909343; called by muse, mutect2, varscan2
- TMC1 | c.814A>T p.R272W | Missense Mutation (SNP) | VAF 175/241 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs111839361, COSV52776648; called by muse, mutect2, varscan2
- TMEM198 | c.926A>G p.N309S | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as rs564632806, COSV54712444; called by muse, mutect2, varscan2
- ZNF362 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as rs1352733345, COSV65031473; called by muse, mutect2, varscan2
- CRACD | c.3351del p.K1117Nfs*53 | Frame Shift Del (DEL) | VAF 23/55 reads (42%) | called by mutect2, pindel, varscan2
- H3C12 | c.120_123del p.R41Tfs*49 | Frame Shift Del (DEL) | VAF 19/95 reads (20%) | called by mutect2, pindel, varscan2
- AK7 | c.1845C>T p.D615= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs199616462, COSV50882050; called by muse, mutect2, varscan2
- CHGB | c.1422C>T p.Y474= | Silent (SNP) | VAF 89/200 reads (45%) | catalogued as rs774814252, COSV66760714; called by muse, mutect2, varscan2
- COG4 | c.270G>C p.L90= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV60423056, COSV60423326; called by muse, varscan2
- DNAH10 | c.13047G>A p.R4349= (on ENST00000409039; = p.R4288= on NM_207437.3) | Silent (SNP) | VAF 61/138 reads (44%) | catalogued as COSV53020028; called by muse, mutect2, varscan2
- DNAH5 | c.11664C>T p.Y3888= | Silent (SNP) | VAF 54/129 reads (42%) | catalogued as rs754874486, COSV54229389, COSV54236409; called by muse, mutect2, varscan2
- FTHL17 | c.183C>T p.D61= | Silent (SNP) | VAF 121/213 reads (57%) | catalogued as rs1183198016, COSV63266432, COSV63267272; called by muse, mutect2, varscan2
- NAT16 | c.321G>A p.L107= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs760126152, COSV55864764; called by muse, mutect2, varscan2
- PCDHA12 | c.1923C>T p.D641= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as rs375548936; called by muse, mutect2, varscan2
- SLC13A2 | c.117G>A p.A39= | Silent (SNP) | VAF 66/159 reads (42%) | catalogued as rs181965873, COSV58995291; called by muse, mutect2, varscan2
- TFPI2 | c.288C>T p.C96= | Silent (SNP) | VAF 37/338 reads (11%) | catalogued as COSV55991852; called by muse, mutect2, varscan2
- TRPM2 | c.2787G>A p.R929= | Silent (SNP) | VAF 119/266 reads (45%) | catalogued as COSV55970500, COSV55973468; called by muse, mutect2, varscan2
- USP10 | c.2262C>A p.V754= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV54749418; called by muse, mutect2, varscan2
- WSCD1 | c.435C>T p.Y145= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV58495852; called by muse, mutect2
- ZNF264 | c.522G>A p.E174= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs754446379, COSV54042147; called by muse, mutect2, varscan2
